Surgical pathology report (de-identified scan), TCGA case TCGA-09-1672, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1672-01A (Primary Tumor).

[page 1 of 7]
FINAL PATHOLOGIC DIAGNOSIS

A. Uterus, cervix, ovaries, tubes, and cul-de-sac nodule, total abdominal

hysterectomy and bilateral salpingo-oophorectomy:

- Right ovary: Low grade serous carcinoma; see comment.
- Right fallopian tube: Soft tissue involved by serous carcinoma.
- Left ovary: Surface papillary tumor; see comment.
- Parametrium: Involved by serosal carcinoma.
- Endometrium: Cystic atrophy.
- Cervix: No significant pathologic abnormality.
- Serosa: No significant pathologic abnormality.
- Myometrium: No significant pathologic abnormality.
- Left fallopian tube: No significant pathologic abnormality.

B. Right pelvic lymph node, excision: Metastatic serous carcinoma; see comment.

C. Left peri-aortic lymph nodes, excision: No tumor in four lymph nodes (0/4).

D. Right peri-aortic lymph nodes, excision: No tumor in three lymph nodes (0/3).

E. Soft tissue, right ovarian vessel, excision: No tumor in three lymph nodes (0/3).

F. Right pelvic lymph node, excision: No tumor in one lymph node (0/1).

G. Right external iliac lymph nodes, excision: Metastatic serous carcinoma in one of four lymph nodes (1/4).

H. Right obturator lymph nodes, excision: Metastatic serous carcinoma in one of five lymph nodes (1/5).

Page 1 of 5

I. Left pelvic lymph nodes, excision: Metastatic serous carcinoma in two lymph nodes (2/15).

J. Portal hepatic lymph nodes, excision: Metastatic serous carcinoma in one lymph node (1/1).

K. Omentum, biopsy: Involved by serosal carcinoma.

L. Appendix, appendectomy: Partial fibrous obliteration, no tumor.

M. Right groin lymph nodes, excision: Metastatic serous carcinoma in three lymph nodes (3/3).

N. Left groin lymph nodes, excision: Metastatic serous carcinoma in

[page 2 of 7]
[REDACTED]

three lymph
nodes (3/4).

[REDACTED]

COMMENT:

Ovarian Tumor Synoptic Comment

- **Location of tumor:** Right (larger) and left (small focus).
- **Type of tumor:** Epithelial: Serous carcinoma arising within a borderline tumor.
- **Grade of tumor:** Low grade.
- **Size of tumor:** 5.5 cm (right).
- **Surface of ovary:** Tumor on surface (both).
- **Condition of capsule:** Intact.
- **Cut surface:** Solid.
- **Color of solid areas:** Tan.
- **Necrosis:** Focal.
- **Lymphatic/vascular invasion:** Present involving lymphovascular spaces.
- **Sites of metastases in pelvis:** Right fallopian tube and parametrium.
- Size of largest pelvic metastasis is 0.6 cm (slide A6, parametrium).
- **Pelvic lymph nodes:** Positive; total positive: 10; total examined: 16; see additional comment below.
- **Sites of metastases in abdomen:** Omentum.
- Size of largest abdominal metastasis is 0.4 cm (slide K2).
- **Para-aortic lymph nodes:** Negative; total examined: 7.
- **Peritoneal cytology:** Positive for adenocarcinoma. Cytology CoPath accession number: [REDACTED]

- **Other findings:** Cystic atrophy of endometrium.
- **FIGO stage:** IIIC.
- **AJCC stage:** pT3cN1M0.

The papillary tumor on the surface of the left ovary in part A is a borderline serous tumor with focal

invasive low grade serous carcinoma.

In Part B, it is difficult to determine if this represents a single lymph node or if the specimen represents matted lymph nodes.

In Part C, psammoma body calcification is present, but no tumor is identified.

Select slides (slides A9, A10, A12, A13) were shown at the departmental [REDACTED]

[REDACTED] on

[REDACTED] and the faculty in attendance concurred with the above diagnoses.

Specimen(s) Received

Page 2 of 5

- A: Uterus, cervix, ovaries, tubes and cul de sac nodule (FS and Oncotech)
- B: Right pelvic lymph node (Oncotech)
- C: Left periaortic lymph nodes
- D: Right periaortic lymph nodes
- E: Right ovarian vessel
- F: Right pelvic lymph node
- G: Right external iliac lymph nodes
- H: Right obturator lymph nodes
- I: Left pelvic lymph nodes
- J: Portal hepatic lymph node

[page 3 of 7]
[REDACTED]

K:Omentum
L:Appendix
M:Right groin lymph nodes
N:Left groin lymph nodes

[REDACTED]

Intraoperative Diagnosis

FS1 (A) Right ovary, biopsy: Adenocarcinoma. ([REDACTED])

Clinical History

The patient is a [REDACTED] with a right ovarian mass who undergoes hysterectomy and bilateral salpingo-oophorectomy.

Gross Description

The specimen is received in fourteen parts, each labeled with the patient's name and unit number.

Parts G-N are received in formalin.

Part A is received fresh in two parts and is additionally labeled "uterus, cervix, ovaries and tubes, and cul-de-sac nodule" and it consists of a hysterectomy and bilateral salpingo-oophorectomy specimen.

The specimen weighs 100 grams and measures 6.5 cm from superior to inferior, 2.3 cm from anterior

to posterior, 5.1 cm from cornu to cornu, sounds to 5.6 cm, and is 22 cm from medial to lateral. The

cervix has a length of 2.5 cm and a width of 1.1 cm. Its os is fish-mouthed and has a 1.1 cm

diameter. The right adnexa has an ovary that measures 5.5 x 4 x 2.5 cm. The surface of the ovary

is pink and violaceous and exhibits multiple excrescences. The surface of the ovary is inked black.

It is serially sectioned to reveal a solid, tan-yellow, firm parenchyma. The right fallopian tube

measures 6 cm in length and has an average diameter of 0.4 cm. The left ovary measures 2.2 x 1.2

x 0.5 cm. It has a smooth, pink to tan surface and exhibits two excrescences that measure 0.6 and

0.3 cm. The surface of the left ovary is also inked black. The left fallopian tube measures 6.5 cm in

length and has an average diameter of 0.5 cm. In addition, there is a paratubal cyst present in the

right adnexa that measures 1.2 x 0.8 x 0.6 cm. The cyst also has a tan nodule at its surface. The

serosal surface of the uterus exhibits an irregularly shaped mass anteriorly that measures 1 x 1 x 0.7

cm. In addition, posteriorly there is an irregularly shaped, tan to pink mass that measures 2.2 x 1.4

x 0.8 cm. Both masses are soft and friable. The uterus is sectioned coronally to reveal an

unremarkable tan endometrium and serial sectioning of the anterior and posterior walls reveals no

lesions within the myometrium. The uterine serosa exhibits multiple white hard nodules that range

[page 4 of 7]
[REDACTED]

in greatest dimension from 0.1 to 0.2 cm. They are present both anteriorly and posteriorly. The anterior endometrium has a thickness of 0.1 cm and the anterior uterine wall has a thickness of 1.7 cm. The posterior endometrium has a thickness of 0.1 cm and the posterior uterine wall has a thickness of 1.4 cm. Representative sections are submitted as follows:

Cassette A1: Frozen section remnant.
Cassette A2: Cervix, both anterior and posterior.
Cassette A3: Anterior wall of uterus.
Cassette A4: Posterior wall of uterus.
Cassette A5: Representative section of posterior serosal mass.
Cassette A6: Representative section of anterior serosal mass.
Cassette A7: Right fallopian tube and fimbria.
Cassette A8: Right paratubal cyst and mass.
Cassettes A9-A11: Right ovary.

Page 3 of 5

Cassette A12: Left fallopian tube and fimbria.
Cassettes A13-A14: Left ovary.

Part B is received fresh and is additionally labeled "right pelvic L node polyp" and consists of an ovoid mass that measures 4 x 3.5 x 2 cm. The mass also has attached yellow fat. A portion of the specimen was taken for Oncotech study. The surface of the specimen is inked black and it is serially sectioned to reveal a rubbery, tan, nodular parenchyma. Representative sections are submitted in cassettes B1-B3.

Part C, additionally labeled "left peri-aortic lymph nodes," consists of a single irregularly shaped, soft to firm, yellow-tan fibrofatty tissue fragment measuring 5 x 1.3 x 0.8 cm. Examination of the specimen reveals four lymph node candidate, which are submitted as follows:

Cassette C1: One lymph node candidate, bisected.
Cassette C2: Two lymph node candidates, bisected.
Cassette C3: One small lymph node candidate, submitted intact.

Part D, additionally labeled "right peri-aortic lymph nodes," consists of a single irregularly shaped, yellow-tan to bright red, fibrofatty tissue fragment measuring 6.2 x 2.3 x 0.6 cm in greatest dimension. Careful examination of the specimen reveals three lymph node candidates, each of which are bisected, then individually submitted in cassettes D1-D3.

Part E, additionally labeled "right ovarian vessel," consists of an elongate, irregularly shaped, red-tan to light yellow tissue fragment measuring 7 x 3.2 x 0.4 cm in greatest dimension. Careful examination reveals a single clamped small vessel, fibrous tissue, and four lymph node candidates.

The lymph node candidates are submitted intact in cassettes E1-E2.

Part F, additionally labeled "right pelvic lymph nodes," consists of two soft to firm, irregular,

[page 5 of 7]
yellow-tan, fibrofatty tissue fragments measuring 3 x 2 x 1 cm in aggregate. No grossly obvious lymph node candidates are identified upon examination. The entire specimen is sectioned and submitted in cassettes F1-F2.

Part G, additionally labeled "right external iliac lymph node," consists of a single, irregularly shaped, soft to firm, yellow-tan, fibrofatty tissue fragment measuring 7.2 x 2.5 x 1 cm.

Careful examination of the specimen reveals four lymph node candidates, which are submitted as follows:

Cassette G1: One lymph node candidate, bisected.

Cassette G2: Two lymph node candidates, bisected.

Cassette G3: One small lymph node candidate, submitted intact.

Part H, additionally labeled "right obturator lymph node," consists of a single, irregularly shaped, soft

to firm, yellow-red, fibrofatty tissue fragment measuring 7 x 3.5 x 0.8 cm.

Examination of the specimen reveals multiple lymph node candidates, which are submitted as follows:

Cassettes H1-H2: One lymph node candidate, bisected.

Cassette H3: Two lymph node candidates, bisected.

Cassette H4: Two small lymph node candidates, submitted intact.

Part I, additionally labeled "left pelvic lymph nodes," consists of multiple soft to firm, irregular,

yellow-tan to bright red, fibrofatty tissue fragments measuring 6.5 x 5 x 1.5 cm in aggregate.

Careful examination of the specimen reveals multiple lymph node candidates, which are submitted as follows:

Cassettes I1-I2: One lymph node candidate, bisected.

Cassettes I3-I4: One lymph node candidate, bisected.

Cassette I5: One lymph node candidate, bisected.

Cassette I6: Two lymph node candidates, bisected.

Cassettes I7-I9: Multiple small lymph node candidates, submitted intact.

Part J, additionally labeled "portal hepatic lymph node," consists of a single firm, off-white to red-tan

tissue fragment measuring 2.6 x 1.7 x 0.8 cm. The specimen is bisected parallel with the long axis

Page 4 of 5

and entirely submitted in cassettes J1-J2.

Part K, additionally labeled "omentum," consists of a single, irregular, yellow-tan to bright red,

irregular sheet of fibrofatty tissue measuring 50 x 18.5 x 1.2 cm in greatest dimension, and weighing

181.5 gm. Visual inspection reveals a single, 1.3 x 0.7 x 0.7 cm, hemorrhagic nodule attached to the

exterior surface of the omentum. Cross-sectioning of this nodule reveals dark red hemorrhagic

tissue. Representative sections are submitted in cassette K1. Further palpation reveals a single area

of firmness. Sectioning reveals a single, 0.5 x 0.3 cm, firm nodule noted embedded within the

fibrofatty tissue. Sections are submitted in cassette K2. The remainder of the

[page 6 of 7]
specimen is serially sectioned at regular intervals, revealing no further discrete nodules, masses, or obvious lymph nodes. Additional sections are submitted in cassettes K3-K4.

Part L, additionally labeled "appendix," consists of a single soft, rubber, pink-tan, vermiform appendix measuring 5.1 cm in length x 0.5 cm in average diameter. The resection margin has been stapled shut using small silver-gray laparoscopic staples. A mesoappendix measures 5.5 x 2 cm in greatest dimension and is soft, without lesion or mass. The mesoappendix is removed from the main portion of the specimen and is serially sectioned to reveal soft, yellow-tan, uniform fibrofatty tissue throughout, without lesion or mass. The mesoappendix is returned to the container. The resection margin of the appendix is inked black. The specimen is then sectioned and cross-sectioned to reveal a single, pink-tan, lined lumen measuring 0.3 cm in average diameter. The appendiceal wall averages 0.1 cm in diameter. No obvious fecal matter or masses fill the lumen of the specimen. The bisected tip is removed to reveal no abnormalities or lesions. The remainder of the specimen is sectioned to reveal no intramural lesions or masses. The specimen is entirely and sequentially submitted from resection margin through appendiceal tip in cassettes L1-L3.

Part M, additionally labeled "right groin lymph node," consists of multiple, soft to firm, off-white and pink to yellow-tan, fibrofatty tissue fragments measuring 7.5 x 5.5 x 2.2 cm in aggregate. Careful examination reveals multiple small to large, firm, irregularly shaped lymph node candidates. The largest lymph node candidate measures 4 x 2.5 x 2.5 cm in greatest dimension. This candidate is inked black and sectioned to reveal a solid white-pink interior. Representative sections are submitted in cassettes M1-M2. The next smallest candidate appears to be a matted conglomerate of multiple lymph node candidates. This portion of the specimen is inked blue and is sectioned to reveal white-pink to red-brown solid tissue. Representative sections are submitted in cassettes M3-M4. The third most prominent lymph node candidate is then sectioned to reveal a solid white to pink-tan interior. A single representative section is submitted in cassette M5.

Part N, additionally labeled "left groin lymph node," consists of multiple segments of firm, irregular, yellow-tan to light pink-red, matted tissue measuring 10.5 x 4.5 x 2.3 cm in aggregate. The largest segment measures 7 x 3.5 x 2 cm. This segment is inked black and serially sectioned, revealing a conglomerate of firm, white-red, fibrous tissue, solid white-tan nodules, and a small

[page 7 of 7]
[REDACTED]

amount of soft,
yellow-tan, fibrofatty tissue. Representative sections of this segment are submitted
in cassettes
N1-N3. The remaining material reveals three additional smaller yet prominent lymph
node
candidates, each of which is bisected and submitted in cassettes N4-N6.
Diagnosis based on gross and microscopic examinations. Final diagnosis made by
attending
pathologist following review of all submitted material.

[REDACTED]

Source: NCI Genomic Data Commons file fa04f4f0-748e-4960-b235-41e54094763d (TCGA-09-1672.103AD514-77DC-42FD-8CF2-31E9DE128A74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).